Somatic mutation profile of tumor specimen TCGA-EM-A1YE-01A (aliquot TCGA-EM-A1YE-01A-11D-A14W-08) from TCGA case TCGA-EM-A1YE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 47.4 years (17,297 days).
Specimen TCGA-EM-A1YE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 041007fc-0b69-451d-b8c1-4b1dd9e64f92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A1YE-11A (Solid Tissue Normal), aliquot TCGA-EM-A1YE-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d1f23f6-02cb-4f2f-a577-d927197108b3

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH7 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.01); catalogued as COSV56775005; called by muse, mutect2, varscan2
- METTL2B | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52309809; called by muse, mutect2, varscan2
- MRTFA | c.1651C>T p.P551S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.832); catalogued as rs752603698, COSV100843985, COSV62934989; called by muse, mutect2, varscan2
- MSI1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1033191114, COSV57457139; called by muse, mutect2, varscan2
- TNRC18 | c.4732G>C p.G1578R | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV68167685; called by muse, mutect2, varscan2
- ZC3H4 | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs759357646, COSV53414953, COSV53418447; called by muse, mutect2, varscan2
- DGKB | c.2067dup p.G690Rfs*3 | Frame Shift Ins (INS) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- GRIK3 | c.447C>T p.Y149= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as rs747127451, COSV66143204; called by muse, mutect2
- OR1J2 | c.480C>T p.T160= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV58944756; called by muse, mutect2
